CCDI case PBCHEU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/cf4337a0-eec9-4629-8217-7ebe5abfd74c

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.3 years (3,018 days).

Biospecimens (3 samples)
- Sample 0DRXE5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRXEC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DRXES: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
